Somatic mutation profile of tumor specimen 0DAS6N from CCDI case PBBJZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.9 years (2,895 days).
Specimen 0DAS6N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b8e48c8-fbb1-433c-bad2-e3cc82d3b835.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAS6O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad9cbc7b-8c04-430b-8232-b49813c81ce9

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
